Surgical pathology report (de-identified scan), TCGA case TCGA-NC-A5HF, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site Washington University - CHUV, specimen TCGA-NC-A5HF-01A (Primary Tumor).

Synoptic translated report

ICD-O-3

Carcinoma, squamous cell,
Keratinizing NOS
8071/3

Site : Left lung inferior lobe

☐ Central ☒ Peripheral ☐ NA

Site: ① Lung, lower lobe
C34.3
JW 2/1/13

Number of lesion :

1. Lung squamous cell carcinoma (first)
2. Lung squamous cell carcinoma (second)

Tumor size:

1. 4 cm (largest diameter)
2. 2.5 cm (largest diameter)

Visceral pleural invasion:

☒ Yes ☐ No ☐ NA

Chest wall invasion :

☐ Yes ☒ No ☐ NA

Histological diagnosis: Moderately differentiated squamous cell carcinoma with focal keratinization.

Node status : NO (0/31)

TNM : pT4 pN0 (0/31) G2 R0

Pathologist signature:

Date:

Site/NA Discrepancy		✓

Source: NCI Genomic Data Commons file 1c395efe-d14b-4a05-b24f-9eb779565bff (TCGA-NC-A5HF.049B234F-D323-4C0B-BF05-DDA265ADA66F.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).